Somatic mutation profile of tumor specimen TCGA-77-A5G1-01A (aliquot TCGA-77-A5G1-01A-11D-A27K-08) from TCGA case TCGA-77-A5G1, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.4 years (27,555 days).
Specimen TCGA-77-A5G1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 047b154f-de5c-4e48-af13-25e8351a117d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-A5G1-10A (Blood Derived Normal), aliquot TCGA-77-A5G1-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb52fd18-777b-43de-b4e8-8fa8f2735b4c

The open-access MAF lists 153 somatic variants for this specimen: 123 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 27, Nonsense Mutation 12, Splice Site 3, Frame Shift Del 3, 3'Flank 1, Intron 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASA1 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as rs1554048066, CM1311704, COSV57191996; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AC004922.1 | c.1062G>C p.Q354H | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); catalogued as COSV99403143; called by muse, mutect2
- ADAM22 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV99717530, COSV99718654; called by muse, mutect2
- ADAMTS18 | c.754C>A p.H252N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99274565; called by muse, mutect2, varscan2
- ADGRB3 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV101002047; called by muse, mutect2
- ADGRD1 | c.652A>T p.K218* | Nonsense Mutation (SNP) | VAF 12/136 reads (9%) | catalogued as COSV99897437; called by muse, mutect2
- AGO4 | c.336G>C p.E112D | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100943123; called by muse, mutect2, varscan2
- AHSG | c.542A>C p.Q181P | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV99890471; called by muse, mutect2
- ALDH1A2 | c.1013G>C p.R338T | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV51095473, COSV99991178; called by muse, mutect2
- ALDH1A2 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179237166, COSV51083375; called by muse, mutect2, varscan2
- ALDH1A2 | c.679A>T p.K227* | Nonsense Mutation (SNP) | VAF 18/151 reads (12%) | catalogued as COSV99991180; called by muse, mutect2, varscan2
- AMPD1 | c.882C>A p.H294Q | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100814824, COSV62418606; called by muse, mutect2
- ANKRD26 | c.3727G>T p.E1243* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV101063477; called by muse, mutect2, varscan2
- ANXA9 | c.665T>A p.F222Y | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV100929179; called by muse, mutect2, varscan2
- AP4B1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.402); catalogued as COSV99871209; called by muse, mutect2, varscan2
- ARID1B | c.3378C>G p.S1126R | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99273006; called by muse, mutect2
- ATP2C1 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV100147050; called by muse, mutect2, varscan2
- BBOF1 | c.380A>C p.E127A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV101223975; called by muse, mutect2, varscan2
- C10orf71 | c.1685C>A p.A562D | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100110744; called by muse, mutect2, varscan2
- C2orf68 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as COSV100084157; called by muse, mutect2
- C6orf118 | c.790T>C p.F264L | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as COSV100025287; called by muse, mutect2
- CACNG5 | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99400871; called by muse, mutect2, varscan2
- CCDC141 | c.2389G>T p.E797* | Nonsense Mutation (SNP) | VAF 12/122 reads (10%) | catalogued as rs1309652462, COSV55369150, COSV55371057; called by muse, mutect2
- CCDC141 | c.2388G>T p.K796N | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV99837638; called by muse, mutect2
- CCDC180 | c.1372-1G>T p.X458_splice | Splice Site (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100827397; called by muse, mutect2
- CCKAR | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV99810600; called by muse, mutect2
- CDH1 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs570930882, COSV104378476, COSV55731335; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / benign / likely benign; called by muse, mutect2
- CDH16 | c.1457T>C p.M486T | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1330986689, COSV100234305; called by muse, mutect2, varscan2
- CDK15 | c.884A>G p.Q295R (on ENST00000652192 / NM_001366386.2; = p.Q244R on NM_139158.2) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.405); catalogued as rs1429753554, COSV99643828; called by muse, mutect2, varscan2
- CHDH | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 15/130 reads (12%) | catalogued as COSV100179924; called by muse, mutect2, varscan2
- CLCN5 | c.682T>A p.C228S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100260453; called by muse, mutect2
- CLSPN | c.3091G>C p.D1031H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV52057437, COSV99231703; called by muse, mutect2, varscan2
- CNTN2 | c.750T>A p.Y250* | Nonsense Mutation (SNP) | VAF 14/142 reads (10%) | catalogued as COSV100085586; called by muse, mutect2
- CNTN2 | c.2717C>A p.T906K | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.116); catalogued as COSV100085587; called by muse, mutect2
- CPEB1 | c.1714G>T p.D572Y (on ENST00000617958; = p.D507Y on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99918065; called by muse, mutect2, varscan2
- CYSLTR1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV64819947; called by muse, mutect2
- DCLK1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV55198564; called by muse, mutect2, varscan2
- DRC1 | c.1528A>C p.K510Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV99985804; called by muse, mutect2
- EFCAB3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100540354, COSV59499818; called by muse, mutect2, varscan2
- FLNC | c.7289C>A p.A2430D | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.906); catalogued as CM1413292, COSV100368938; called by muse, mutect2, varscan2
- FURIN | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV99184811; called by muse, mutect2, varscan2
- FUT2 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1406380167, COSV101218167; called by muse, mutect2, varscan2
- GMEB1 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99603545; called by muse, mutect2, varscan2
- GPR183 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100854449; called by muse, mutect2
- GRIK5 | c.385C>A p.Q129K | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.207); catalogued as COSV99491490; called by muse, mutect2, varscan2
- GRIN2B | c.4007A>G p.Y1336C | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101663218; called by muse, mutect2, varscan2
- GTF3C1 | c.5336C>A p.T1779K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as COSV100649796; called by muse, mutect2
- HERC1 | c.12274G>A p.G4092R | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101497059; called by muse, mutect2
- HGF | c.1595C>A p.A532E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV99738816; called by muse, mutect2
- HOXC13 | c.803C>G p.T268S | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); catalogued as COSV99673629; called by muse, mutect2, varscan2
- HYDIN | c.12314C>A p.T4105N | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV101125255; called by muse, mutect2
- IL1RAPL2 | c.1303C>A p.L435M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100782170; called by muse, mutect2, varscan2
- INHA | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99217641; called by muse, mutect2, varscan2
- ITIH1 | c.2191G>A p.G731R | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs142551669; called by muse, mutect2, varscan2
- KCNS2 | c.337T>G p.F113V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as COSV99751576; called by muse, mutect2, varscan2
- KDM3A | c.349A>G p.K117E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV100461098; called by muse, varscan2
- KDR | c.2968G>T p.E990* | Nonsense Mutation (SNP) | VAF 31/177 reads (18%) | catalogued as COSV99818906; called by muse, mutect2, varscan2
- KIF2A | c.680G>T p.C227F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101136723; called by muse, mutect2
- KRTAP10-7 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.023); catalogued as rs1397064711, COSV100170360; called by muse, mutect2
- LRRTM1 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99703348; called by muse, mutect2
- LRRTM1 | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as COSV99703351; called by muse, mutect2
- MATN4 | c.1652T>A p.F551Y (on ENST00000372754; = p.F510Y on NM_003833.4) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | PolyPhen probably damaging (0.998); catalogued as COSV100637189; called by muse, mutect2
- MBD1 | c.47A>T p.K16M | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99497449; called by muse, mutect2, varscan2
- MED25 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100457745; called by muse, mutect2, varscan2
- MIA2 | c.1299G>T p.K433N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV99698337; called by muse, mutect2, varscan2
- MKS1 | c.1488C>T p.S496= | Splice Region (SNP) | VAF 22/139 reads (16%) | catalogued as COSV99836828; called by muse, mutect2, varscan2
- MTNR1B | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99925408; called by muse, mutect2, varscan2
- MUC16 | c.23983T>A p.S7995T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.014); catalogued as COSV101202076; called by muse, mutect2, varscan2
- MYT1L | c.2444G>T p.W815L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101221558; called by muse, mutect2, varscan2
- NEUROD1 | c.658T>C p.S220P | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99717085; called by muse, mutect2
- NF1 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100648470, COSV62203437; called by muse, mutect2
- NINL | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99626569; called by muse, mutect2, varscan2
- NOTCH4 | c.5693G>C p.R1898P | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV66679069; called by muse, mutect2, varscan2
- NRXN1 | c.3464G>T p.G1155V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100457352; called by muse, mutect2, varscan2
- NXF3 | c.1543T>C p.S515P | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV101222109; called by muse, mutect2, varscan2
- OR4K13 | c.682C>A p.R228S | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.44); catalogued as rs762850065, COSV100237931; called by muse, mutect2, varscan2
- OR4X1 | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100186868; called by muse, mutect2, varscan2
- OR51F1 | c.379A>T p.T127S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100598929; called by muse, mutect2, varscan2
- OR9A2 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100628302; called by muse, mutect2
- PAPPA2 | c.4152-1G>A p.X1384_splice | Splice Site (SNP) | VAF 10/103 reads (10%) | catalogued as COSV100868783; called by muse, mutect2, varscan2
- PARPBP | c.1451A>T p.N484I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100268348; called by muse, mutect2, varscan2
- PAX7 | c.1153C>A p.Q385K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100947012; called by muse, mutect2, varscan2
- PBX1 | c.907A>C p.N303H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100905302; called by muse, mutect2
- PCDHA2 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.043); catalogued as COSV100974183; called by muse, mutect2, varscan2
- PCDHB14 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV99506067, COSV99506370; called by muse, mutect2, varscan2
- PCLO | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.116); catalogued as rs1402765191, COSV100439086; called by muse, mutect2, varscan2
- PKHD1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV61880520; called by muse, mutect2, varscan2
- PLAU | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV101032442; called by muse, mutect2, varscan2
- PLEKHG2 | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52689036; called by muse, mutect2, varscan2
- PMS1 | c.2701A>G p.I901V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV59719073; called by muse, mutect2, varscan2
- POLE | c.4145G>T p.R1382L | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV100268624; called by muse, mutect2, varscan2
- PPP1R3A | c.1693C>A p.L565M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV99494650; called by muse, mutect2, varscan2
- RBBP6 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs987725462, COSV100155119; called by muse, mutect2
- RBM47 | c.358C>G p.H120D | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99921895; called by muse, mutect2
- RGS7BP | c.106A>G p.R36G | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100471452; called by muse, mutect2, varscan2
- RUNX1 | c.517C>T p.P173S (on ENST00000344691 / NM_001001890.3; = p.P200S on NM_001754.5) | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55880859, COSV99038621; called by muse, mutect2
- RYR1 | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100617250; called by muse, mutect2, varscan2
- RYR3 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs757634718, COSV101211789; called by muse, mutect2
- SLC17A6 | c.884C>A p.A295E | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as COSV99582554; called by muse, mutect2
- SLC30A9 | c.914T>A p.M305K | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100048572; called by muse, mutect2
- SPTBN1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100443582; called by muse, mutect2
- STRIP2 | c.2218C>G p.R740G | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50804158, COSV99974241; called by muse, mutect2, varscan2
- SYNE1 | c.15199G>T p.G5067C (on ENST00000367255 / NM_182961.4; = p.G4996C on NM_033071.3) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV55093447, COSV99583168; called by muse, mutect2, varscan2
- THSD7A | c.4208T>C p.L1403P | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101439807; called by muse, mutect2
- TLN2 | c.3995A>G p.N1332S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs776896175, COSV100170300; called by muse, mutect2, varscan2
- TMEM198 | c.946-2A>T p.X316_splice | Splice Site (SNP) | VAF 11/82 reads (13%) | catalogued as COSV99525963; called by muse, mutect2, varscan2
- TMX3 | c.1178G>T p.C393F | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV100218613; called by muse, mutect2, varscan2
- TNIK | c.3775G>T p.E1259* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99460151; called by muse, mutect2, varscan2
- TTC30B | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101282816; called by muse, mutect2
- TTN | c.89086G>T p.G29696* (on ENST00000591111; = p.G22272* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as COSV100634329; called by muse, mutect2, varscan2
- TTN | c.23777G>C p.C7926S (on ENST00000591111; = p.C6999S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | PolyPhen probably damaging (0.909); catalogued as COSV100634333; called by muse, mutect2
- TUBGCP3 | c.2275A>G p.I759V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1350553674, COSV99997378; called by muse, mutect2, varscan2
- ZEB1 | c.3292G>T p.A1098S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV100315247; called by muse, mutect2
- ZNF180 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 32/104 reads (31%) | catalogued as COSV99660115; called by muse, mutect2, varscan2
- ZNF473 | c.1529C>T p.T510I | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs1189627641, COSV99569197; called by muse, mutect2, varscan2
- ZSCAN5B | c.1385C>G p.S462C | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs371249672, COSV62000743; called by muse, mutect2
- CD3E | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- GFRAL | c.898del p.E300Rfs*42 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel, varscan2
- GPR179 | c.1055G>C p.G352A (on ENST00000621958; = p.G351A on NM_001004334.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- NRXN3 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- PHF12 | c.543del p.N181Kfs*15 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- SMARCA2 | c.1368del p.L456Ffs*51 | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | called by mutect2, pindel, varscan2
- ARHGAP28 | c.1173G>A p.K391= (on ENST00000383472 / NM_001366230.1; = p.K232= on NM_001010000.3) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99151623; called by muse, mutect2, varscan2
- ASXL2 | c.2904G>T p.L968= | Silent (SNP) | VAF 32/251 reads (13%) | catalogued as COSV99712226; called by muse, mutect2, varscan2
- ATP5MC3 | c.357G>T p.L119= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- AXIN1 | c.357T>C p.F119= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99250438; called by muse, mutect2, varscan2
- CENPE | c.7407A>T p.L2469= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99479456; called by muse, mutect2
- CPT1B | c.783T>C p.L261= | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as COSV100376888; called by muse, mutect2, varscan2
- DCP1A | c.693A>G p.Q231= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs782675604, COSV99588287; called by muse, mutect2, varscan2
- DNTT | c.66G>A p.L22= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs779048686, COSV100960798; called by muse, mutect2, varscan2
- EPB41L3 | c.618C>T p.C206= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100550585; called by muse, mutect2, varscan2
- FAN1 | c.1366C>T p.L456= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV100756120, COSV62951160, COSV62951351; called by muse, mutect2
- FREM1 | c.4923C>T p.L1641= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs886063767, COSV101085672; ClinVar: uncertain significance; called by muse, mutect2
- FZD10 | c.1332C>A p.I444= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV57472370, COSV99969658; called by muse, mutect2, varscan2
- GBF1 | c.4572G>A p.L1524= (on ENST00000369983 / NM_001377137.1; = p.L1523= on NM_004193.3) | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV100890716; called by muse, mutect2
- GLI1 | c.1242C>G p.P414= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99954801; called by muse, mutect2, varscan2
- HCK | c.402C>A p.A134= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV99394713; called by muse, mutect2, varscan2
- HPN | c.984T>C p.Y328= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs765151900, COSV99385401; called by muse, mutect2
- NEUROD1 | c.498C>T p.V166= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV99717086; called by muse, mutect2, varscan2
- OR6T1 | c.849C>A p.P283= | Silent (SNP) | VAF 21/215 reads (10%) | catalogued as COSV100190236; called by muse, mutect2, varscan2
- OR7D4 | c.912C>A p.L304= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100432897; called by muse, mutect2, varscan2
- OTOF | c.5664C>T p.G1888= (on ENST00000272371 / NM_194248.3; = p.G1121= on NM_004802.4) | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV99719276; called by muse, mutect2, varscan2
- SLCO4A1 | c.480C>T p.V160= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV53892222; called by muse, mutect2, varscan2
- TMEM117 | c.756T>G p.L252= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as COSV99863964; called by muse, mutect2
- TTK | c.915A>G p.E305= | Silent (SNP) | VAF 26/207 reads (13%) | catalogued as rs775557174, COSV100036681; called by muse, mutect2, varscan2
- USP29 | c.1395T>A p.L465= | Silent (SNP) | VAF 7/171 reads (4%) | catalogued as rs990304492, COSV99518823; called by muse, mutect2
- VCAN | c.10143C>A p.S3381= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV54103901, COSV99427660; called by muse, mutect2, varscan2
- ZAN | c.4620C>A p.A1540= | Silent (SNP) | VAF 21/154 reads (14%) | catalogued as COSV100770538; called by muse, mutect2, varscan2
- ZNF365 | c.96A>G p.G32= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV101238005; called by muse, mutect2, varscan2
- EXT2 | c.1173+14123A>T | Intron (SNP) | VAF 20/144 reads (14%) | catalogued as COSV100640708; called by muse, mutect2, varscan2
- FAM27E5 | n.239C>A | RNA (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2, varscan2
- SMIM12 | chr1:34855303 T>A | 3'Flank (SNP) | VAF 11/102 reads (11%) | catalogued as COSV101315086; called by muse, mutect2, varscan2
